Somatic mutation profile of tumor specimen C3N-01758-03 (aliquot CPT0163340006) from CPTAC case C3N-01758, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 59.4 years (21,708 days).
Specimen C3N-01758-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 972ef07f-b2da-4af3-8d62-74ac6be85a09.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01758-31 (Blood Derived Normal), aliquot CPT0163400002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0bdf5cb1-7fc8-41c0-9683-4ef8bc24d73e

The open-access MAF lists 74 somatic variants for this specimen: 54 protein-altering or splice-affecting, 14 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 14, Intron 2, Frame Shift Del 2, RNA 2, Translation Start Site 1, 3'UTR 1, Splice Site 1, Nonsense Mutation 1, In Frame Del 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 157/416 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANK3 | c.6853G>C p.D2285H | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs777474903, COSV55064792; called by muse, mutect2, varscan2
- ASCC2 | c.1409C>A p.S470Y | Missense Mutation (SNP) | VAF 71/332 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV57074329; called by muse, mutect2, varscan2
- ATG12 | c.35C>A p.P12H | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.754); catalogued as rs535376486; called by muse, mutect2, varscan2
- CYTIP | c.47C>A p.A16E | Missense Mutation (SNP) | VAF 37/207 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV51634105; called by muse, mutect2, varscan2
- DAG1 | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58184702; called by muse, mutect2, varscan2
- DNAH7 | c.9826G>A p.E3276K | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV56781990; called by muse, mutect2, varscan2
- EYS | c.19G>A p.V7I | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as rs377622148, COSV100675758; called by muse, mutect2, varscan2
- GCC2 | c.2975A>G p.K992R | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369476264; called by muse, mutect2, varscan2
- KATNIP | c.4609G>A p.V1537M | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs759531126, COSV99851504; called by muse, mutect2, varscan2
- KMT2A | c.5655T>C p.N1885= | Splice Region (SNP) | VAF 20/139 reads (14%) | catalogued as rs782817600, COSV63292091; called by muse, mutect2, varscan2
- LOXHD1 | c.1855C>T p.R619W | Missense Mutation (SNP) | VAF 35/249 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1220335121, COSV59665550; called by muse, mutect2, varscan2
- MYBPC2 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); catalogued as rs375154247; called by muse, mutect2, varscan2
- MYH15 | c.1721A>G p.H574R | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as rs757975090; called by muse, mutect2, varscan2
- NOTCH1 | c.4233del p.Y1412Tfs*33 | Frame Shift Del (DEL) | VAF 39/121 reads (32%) | catalogued as COSV53059517; called by mutect2, pindel, varscan2
- PCDHGB7 | c.1198A>T p.N400Y | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99546020; called by muse, mutect2, varscan2
- PKD1L1 | c.5720G>A p.R1907H | Missense Mutation (SNP) | VAF 61/311 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as rs760659567, COSV56960930; called by muse, mutect2, varscan2
- POTEF | c.1699G>A p.D567N | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV100665093; called by mutect2, varscan2
- SLC15A3 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs757578910; called by mutect2, varscan2
- SLC9A3 | c.1075G>A p.V359M | Missense Mutation (SNP) | VAF 84/263 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV53804488; called by muse, mutect2, varscan2
- SPN | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs762062584, COSV64070581; called by muse, varscan2
- SPON1 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1166818070; called by muse, mutect2, varscan2
- SYNJ1 | c.4339G>C p.D1447H | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.018); catalogued as COSV59151211; called by muse, mutect2
- TREML1 | c.779C>G p.P260R | Missense Mutation (SNP) | VAF 19/486 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV64191535; called by muse, mutect2
- ALCAM | c.404C>G p.S135C | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ALPG | c.1063G>T p.D355Y | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.531); called by mutect2, varscan2
- CELA3A | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 14/216 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- CEP162 | c.1267A>G p.M423V | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNGB1 | c.3695A>T p.E1232V | Missense Mutation (SNP) | VAF 90/402 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- DCAF4L1 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- EIF3E | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 26/158 reads (16%) | called by muse, mutect2, varscan2
- FAM24A | c.94T>C p.C32R | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- GREB1L | c.3226G>T p.A1076S | Missense Mutation (SNP) | VAF 90/405 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HECTD4 | c.11137A>T p.N3713Y | Missense Mutation (SNP) | VAF 99/420 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ICE2 | c.775A>T p.M259L | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGA8 | c.1414G>T p.A472S | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2
- KCNB1 | c.2471G>T p.G824V | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- LCORL | c.1295T>A p.L432Q | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.966); called by muse, mutect2
- LIMCH1 | c.1601C>G p.P534R | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP10 | c.2347G>A p.E783K | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- OR52L1 | c.968G>T p.R323I | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- PPP1R12C | c.785C>T p.T262I | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBM33 | c.1193C>T p.P398L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SCAMP1 | c.676A>T p.I226F | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SIGLEC14 | c.244G>A p.V82M | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); called by muse, mutect2
- SLC25A6 | c.645G>T p.M215I | Missense Mutation (SNP) | VAF 28/355 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- SLCO6A1 | c.1117T>C p.C373R | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SPAG16 | c.1488C>A p.S496R | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.137); called by muse, mutect2
- STX7 | c.86-2A>T p.X29_splice | Splice Site (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- TGFBR2 | c.495del p.Q166Kfs*2 | Frame Shift Del (DEL) | VAF 26/113 reads (23%) | called by mutect2, pindel, varscan2
- TMEM132E | c.2099C>T p.A700V (on ENST00000321639; = p.A790V on NM_001304438.2) | Missense Mutation (SNP) | VAF 113/496 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TWIST2 | c.232C>G p.R78G | Missense Mutation (SNP) | VAF 63/323 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UTRN | c.8083G>T p.D2695Y | Missense Mutation (SNP) | VAF 90/378 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ZNF696 | c.14_16del p.G5del | In Frame Del (DEL) | VAF 48/282 reads (17%) | called by pindel, varscan2
- ADGRV1 | c.12435G>A p.K4145= | Silent (SNP) | VAF 38/189 reads (20%) | called by muse, mutect2, varscan2
- ANKRD30A | c.1578C>A p.A526= (on ENST00000611781; = p.A470= on NM_052997.2) | Silent (SNP) | VAF 14/119 reads (12%) | called by muse, mutect2, varscan2
- EGFR | c.3432C>G p.P1144= | Silent (SNP) | VAF 47/227 reads (21%) | called by muse, mutect2, varscan2
- ELAPOR2 | c.2943T>C p.A981= (on ENST00000450689 / NM_001142749.3; = p.A814= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 20/79 reads (25%) | called by muse, mutect2, varscan2
- FKBP6 | c.234G>A p.R78= | Silent (SNP) | VAF 45/292 reads (15%) | called by muse, mutect2, varscan2
- GASK1B | c.138C>T p.I46= | Silent (SNP) | VAF 19/126 reads (15%) | catalogued as rs1273164502, COSV99647394; called by muse, mutect2, varscan2
- GMCL1 | c.1326A>T p.G442= | Silent (SNP) | VAF 17/106 reads (16%) | called by muse, mutect2, varscan2
- GTF3C2 | c.396C>T p.S132= | Silent (SNP) | VAF 41/215 reads (19%) | called by muse, mutect2, varscan2
- KCNB1 | c.2472C>T p.G824= | Silent (SNP) | VAF 29/179 reads (16%) | catalogued as rs375177375; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO18B | c.6624C>T p.G2208= | Silent (SNP) | VAF 90/359 reads (25%) | catalogued as rs762797172; called by muse, mutect2, varscan2
- PARM1 | c.264G>A p.E88= | Silent (SNP) | VAF 27/406 reads (7%) | called by muse, mutect2
- SETBP1 | c.1203G>T p.R401= | Silent (SNP) | VAF 42/199 reads (21%) | called by muse, mutect2, varscan2
- TRPM2 | c.1344C>T p.G448= | Silent (SNP) | VAF 46/272 reads (17%) | catalogued as rs1176412485, COSV104394362; called by muse, mutect2, varscan2
- VPS13B | c.510C>T p.S170= | Silent (SNP) | VAF 9/105 reads (9%) | catalogued as rs749836132, COSV62018431; ClinVar: likely benign; called by muse, mutect2
- AC104078.1 | n.264C>A | RNA (SNP) | VAF 55/243 reads (23%) | called by muse, mutect2, varscan2
- AKAP7 | c.*776G>A | 3'UTR (SNP) | VAF 17/100 reads (17%) | called by muse, mutect2, varscan2
- CHRNA7 | c.-31G>A | 5'UTR (SNP) | VAF 32/227 reads (14%) | called by muse, mutect2, varscan2
- KIF1B | c.2115+7293G>A | Intron (SNP) | VAF 11/86 reads (13%) | called by muse, mutect2, varscan2
- MRRFP1 | n.76T>A | RNA (SNP) | VAF 51/118 reads (43%) | called by muse, mutect2, varscan2
- RUFY3 | c.178+18888A>T | Intron (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
